CPTAC case C3N-03026 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/020341c4-f88d-4c35-86b1-988b9d1d80be

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1954; Vital status: Dead; Days to death: 2,198 days (6.0 years); Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 63.4 years (23,148 days); Year of diagnosis: 2017; Last known disease status: Tumor free; Days to last known disease status: 2,198 days (6.0 years); Progression or recurrence: no; Days to last follow up: 2,198 days (6.0 years).

Follow-up (5 entries)
- Days to follow up: 340 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 841 days (2.3 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,218 days (3.3 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,578 days (4.3 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 2,198 days (6.0 years); Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 5.

Biospecimens (4 samples)
- Sample C3N-03026-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -27 days; Initial weight: 76 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03026-02: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -27 days; Initial weight: 63 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03026-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -27 days; Initial weight: 112 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03026-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Initial weight: 10 mg.
